Gene-level copy-number profile of tumor specimen TCGA-AA-3679-01A from TCGA case TCGA-AA-3679, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 59.2 years (21,611 days).
Specimen TCGA-AA-3679-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d913fa5c-e2da-4d6b-8078-7e88593e20b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3679-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8d2edb8f-cb3e-4ce4-8d19-8f01e76a4511

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,723; copy number 2: 31,182; copy number 3: 17,811; copy number 4: 3,719; copy number 5: 857; copy number 7: 178; copy number 8: 248; copy number 9: 6; copy number 11: 36; copy number 12: 12; copy number 16: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3679-01A-02D-0903-01): tumor purity 0.78, ploidy 2.49, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,377 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:23,979,700–24,321,031, 2 genes, copy number 5 (within-gene range 4–5): AL359736.1, SPATA13.
- chr13:24,122,065–55,174,548, 577 genes, copy number 5 (broad region; genes not listed).
- chr13:68,634,190–87,458,407, 181 genes, copy number 5–7 (broad region; genes not listed).
- chr17:21,123,364–22,205,154, 28 genes, copy number 5 (within-gene range 3–5): DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4.
- chr20:40,685,848–43,189,970, 27 genes, copy number 5–9 (within-gene range 3–16): MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3, PTPRT.
- chr20:42,968,743–47,860,672, 168 genes, copy number 5–16 (within-gene range 3–16) (broad region; genes not listed).
- chr20:47,974,137–64,313,132, 394 genes, copy number 5–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,411. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
